Somatic mutation profile of tumor specimen TCGA-B2-5635-01B (aliquot TCGA-B2-5635-01B-04D-A270-10) from TCGA case TCGA-B2-5635, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 74.4 years (27,183 days).
Specimen TCGA-B2-5635-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52679f8e-7037-43a8-a383-9444352639db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-5635-10A (Blood Derived Normal), aliquot TCGA-B2-5635-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb8dccd3-1bc6-4555-a3da-531fefec3212

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, Frame Shift Del 5, Splice Site 2, 5'Flank 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.431del p.G144Dfs*15 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | catalogued as rs869025651, CM058403, CM982008, COSV56544477, COSV56545017; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACOX3 | c.70T>C p.Y24H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62710847; called by muse, mutect2, varscan2
- AKR1B15 | c.809A>G p.K270R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV71151044, COSV71152438; called by muse, mutect2, varscan2
- AMOTL1 | c.1970A>G p.N657S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV58565068; called by muse, varscan2
- C1orf198 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.367); catalogued as COSV100793515; called by muse, mutect2, varscan2
- CADPS | c.3724G>C p.D1242H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51867480; called by muse, mutect2, varscan2
- CHRDL2 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs1272782634, COSV55221695; called by muse, mutect2, varscan2
- DAPK1 | c.982A>G p.M328V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs370466694; called by muse, mutect2, varscan2
- DDX24 | c.1549C>G p.P517A | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs754809380; called by muse, mutect2
- DNAH5 | c.12436T>G p.S4146A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as COSV54204617, COSV54231804; called by muse, mutect2, varscan2
- DOP1A | c.7054G>C p.V2352L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV52706914; called by muse, mutect2, varscan2
- DVL3 | c.1988G>C p.G663A | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.142); catalogued as COSV99491018; called by muse, mutect2, varscan2
- EPB41L5 | c.329-1del p.X110_splice | Splice Site (DEL) | VAF 15/95 reads (16%) | catalogued as COSV99758863; called by mutect2, pindel, varscan2
- F12 | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as rs773373088, COSV99499971; called by muse, mutect2, varscan2
- GCNT2 | c.929T>C p.V310A (on ENST00000379597 / NM_001374747.1; = p.V308A on NM_001491.3) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.028); catalogued as COSV53941111; called by muse, varscan2
- GLI3 | c.2432-1G>T p.X811_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | catalogued as COSV101230108; called by muse, mutect2, varscan2
- IFT140 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.663); catalogued as COSV68485941; called by muse, mutect2, varscan2
- KAT6B | c.5771C>G p.S1924C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV54742321; called by muse, mutect2, varscan2
- KCNJ4 | c.1257C>G p.F419L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs755886046, COSV100341556, COSV57856658; called by muse, mutect2, varscan2
- KCNV2 | c.1385A>G p.D462G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66055548; called by muse, mutect2, varscan2
- MBTD1 | c.1090T>A p.F364I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV64502808; called by muse, mutect2, varscan2
- MCCC1 | c.1151C>G p.A384G | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55606382; called by muse, mutect2, varscan2
- MUC16 | c.21268C>G p.L7090V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763621010, COSV67445588; called by muse, mutect2
- NBAS | c.2502G>T p.M834I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV55712855, COSV55713784; called by muse, mutect2, varscan2
- NDUFC1 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1291900266, COSV55499317; called by muse, mutect2, varscan2
- NEBL | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV65799488; called by muse, mutect2, varscan2
- PKP4 | c.2858C>A p.A953E | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV61577877; called by muse, mutect2, varscan2
- PLEKHA2 | c.33_34del p.C11Wfs*9 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs940962664; called by pindel, varscan2
- POLI | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99471281; called by muse, mutect2, varscan2
- PXDN | c.3205G>A p.A1069T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53227201, COSV53241593; called by muse, mutect2, varscan2
- RDX | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs150863373; called by muse, mutect2, varscan2
- RTN1 | c.593A>G p.D198G | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774918300, COSV50718848, COSV99955912; called by muse, mutect2, varscan2
- TM6SF1 | c.976A>G p.R326G | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51943091, COSV51944282; called by muse, mutect2, varscan2
- TSNAXIP1 | c.892A>T p.S298C | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV54648201; called by muse, mutect2
- TSNAXIP1 | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV54648209; called by muse, mutect2
- USF3 | c.914A>G p.H305R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV57069902; called by muse, mutect2, varscan2
- ZC3H13 | c.4528G>A p.E1510K (on ENST00000242848 / NM_001330565.2; = p.E1511K on NM_015070.6) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.985); catalogued as COSV54458774; called by muse, mutect2, varscan2
- ZNF433 | c.1820T>C p.M607T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.159); catalogued as COSV61398410; called by muse, mutect2, varscan2
- AHNAK2 | c.14814_14831del p.E4938_A4944delinsD | In Frame Del (DEL) | VAF 7/17 reads (41%) | called by mutect2, varscan2
- APC | c.3909_3915del p.I1304Kfs*2 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | called by mutect2, pindel, varscan2
- COPA | c.2176_2183del p.R726Hfs*13 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel
- ESCO2 | c.417del p.K139Nfs*6 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- ABL2 | c.114G>A p.A38= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100859755; called by muse, mutect2, varscan2
- CBFA2T3 | c.1551C>T p.H517= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1169750562, COSV51923312; called by muse, mutect2, varscan2
- CHD5 | c.567T>G p.G189= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV52407880; called by muse, mutect2
- DSG1 | c.3066C>T p.H1022= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV57133270; called by muse, mutect2, varscan2
- IGF1R | c.66G>A p.A22= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV51270402; called by muse, mutect2, varscan2
- OGG1 | c.180G>C p.A60= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs368830432, COSV57351350; called by muse, mutect2, varscan2
- SIMC1 | c.1053G>A p.R351= (on ENST00000443967 / NM_001308196.1; = p.R370= on NM_001308195.2) | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as COSV57900197; called by muse, mutect2, varscan2
- SLC5A3 | c.309G>C p.R103= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV62967904; called by muse, mutect2, varscan2
- SLIT2 | c.1998T>C p.F666= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV56560594; called by muse, mutect2, varscan2
- TEKT2 | c.1116G>T p.R372= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99255650; called by muse, mutect2
- TOPBP1 | c.717A>G p.T239= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99605950; called by muse, mutect2, varscan2
- ATP6V1G2 | chr6:31548402 C>T | 5'Flank (SNP) | VAF 3/22 reads (14%) | catalogued as rs1280045382, COSV100385504; called by muse, mutect2
- DUOXA1 | chr15:45117743 del C | 3'Flank (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
